Somatic mutation profile of tumor specimen TCGA-AK-3443-01A (aliquot TCGA-AK-3443-01A-01D-0966-08) from TCGA case TCGA-AK-3443, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: GX; Age at diagnosis: 45.4 years (16,578 days).
Specimen TCGA-AK-3443-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d246d0d-da62-4155-8ff3-6ea06c9150e4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AK-3443-10A (Blood Derived Normal), aliquot TCGA-AK-3443-10A-01D-0966-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d5426177-59de-4de7-a929-6c2e26b59fa8

The open-access MAF lists 8 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Intron 1, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP10 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.094); catalogued as rs141935259; called by muse, mutect2, varscan2
- SOS2 | c.1373A>G p.H458R | Missense Mutation (SNP) | VAF 161/380 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.056); catalogued as rs766792092; called by muse, mutect2, varscan2
- FRG1 | c.433-11_433-1delinsTGTTTCACTTA p.X145_splice | Splice Site (ONP) | VAF 6/51 reads (12%) | called by mutect2*, pindel
- HS3ST2 | c.425C>T p.A142V | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MTMR3 | c.228A>G p.I76M | Missense Mutation (SNP) | VAF 69/172 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- PCDHB3 | c.2360C>A p.P787H | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2
- AC092718.9 | chr16:81156877 G>A | 3'Flank (SNP) | VAF 33/81 reads (41%) | catalogued as rs375515044; called by muse, mutect2, varscan2
- SPEG | c.389-1514G>A | Intron (SNP) | VAF 163/468 reads (35%) | catalogued as rs1228606232; called by muse, mutect2, varscan2
